Surgical pathology report (de-identified scan), TCGA case TCGA-DD-AACX, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-AACX-01A (Primary Tumor).

[page 1 of 2]
LINICAL DIAGNOSIS: R/O HCC

Specimen : liver

Gross Photo :

GROSS:

The gross specimen consists of three cores of pale tan fragmented needle-biopsied liver tissue, 1.6 x 0.2 x 0.1 cm in aggregates. Entirely submitted.

Block x 1

SPECIAL STAIN:

Mucicarmine and trichrome stains reveal no significant change.

Reticulin stain reveals disruption of reticulin frame work.

NOT reported. Gross:

NOT reported. Gross:

ICD O-3

Carcinoma, hepatocellular NOS
8170/3

Site: Liver C22.0

JN 5/19/14

Stomach, antrum, scopic, atypical glands

Stomach, antrum, scopic, chronic gastritis

liver,needle,hepatocellular carcinoma

T56000, P28, M81703

DIAGNOSIS:

Liver, CT guided needle biopsy:

[page 2 of 2]
Hepatocellular carcinoma, well differentiated (see NOTE)
(Edmondson-steiner grade (1/4)

NOTE: This case was consulted to Dr.

Suggestion :

Source: NCI Genomic Data Commons file a448cf34-5b54-4d66-9bb8-71efef73f7f4 (TCGA-DD-AACX.0911F16A-EA5A-45F4-906E-4F2163096A78.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).